Somatic mutation profile of tumor specimen TCGA-13-0765-01A (aliquot TCGA-13-0765-01A-01W-0372-09) from TCGA case TCGA-13-0765, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 50.9 years (18,574 days).
Specimen TCGA-13-0765-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b431ed8-345b-4ae6-9bad-5ce1abf420ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0765-10A (Blood Derived Normal), aliquot TCGA-13-0765-10A-01W-0372-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/156cfa70-d34f-4fd7-83f1-0c3765507f73

The open-access MAF lists 35 somatic variants for this specimen: 26 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 8, Splice Site 2, Frame Shift Del 1, Nonsense Mutation 1, 3'UTR 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C6 | c.2450A>G p.K817R | Missense Mutation (SNP) | VAF 222/886 reads (25%) | hotspot (GDC flag); SIFT tolerated (0.24); PolyPhen benign (0.259); catalogued as COSV54704910, COSV54705322; called by muse, mutect2, varscan2
- TP53 | c.783-6_791dup p.S260_L264dup | In Frame Ins (INS) | VAF 18/46 reads (39%) | hotspot (GDC flag); catalogued as COSV52683555; called by mutect2, varscan2
- ARMCX5 | c.1031C>G p.T344S | Missense Mutation (SNP) | VAF 337/493 reads (68%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.995); catalogued as COSV55765924; called by muse, mutect2, varscan2
- ASTN1 | c.1277G>T p.R426L | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV56061957, COSV56086029; called by muse, mutect2, varscan2
- ATRNL1 | c.3176C>G p.A1059G | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV58074913; called by muse, mutect2, varscan2
- CYLC1 | c.1186A>C p.K396Q | Missense Mutation (SNP) | VAF 75/115 reads (65%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.964); catalogued as COSV61410023; called by muse, mutect2, varscan2
- DNAJC14 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 140/368 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.254); catalogued as COSV57912208; called by muse, mutect2, varscan2
- GSX1 | c.712A>T p.K238* | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | catalogued as COSV57232434; called by muse, mutect2, varscan2
- IGKV1-6 | c.233G>C p.S78T | Missense Mutation (SNP) | VAF 38/539 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as rs539713264; called by muse, mutect2
- IQCG | c.1213C>G p.R405G | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99502110, COSV99502760; called by muse, mutect2, varscan2
- LIMK1 | c.827C>A p.P276Q | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV60280034, COSV60280406; called by muse, mutect2, varscan2
- LPAR1 | c.224A>G p.Y75C | Missense Mutation (SNP) | VAF 127/295 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.95); catalogued as rs371341035; called by muse, mutect2, varscan2
- MAP1LC3C | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.047); catalogued as COSV61803484; called by muse, mutect2, varscan2
- NEDD4 | c.2279C>T p.P760L (on ENST00000508342 / NM_001284338.1; = p.P341L on NM_006154.4) | Missense Mutation (SNP) | VAF 17/190 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV100163395, COSV100163751; called by muse, mutect2
- NEDD4 | c.2278C>T p.P760S (on ENST00000508342 / NM_001284338.1; = p.P341S on NM_006154.4) | Missense Mutation (SNP) | VAF 17/189 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.244); catalogued as COSV59058786; called by muse, mutect2
- OR51I2 | c.733A>G p.I245V | Missense Mutation (SNP) | VAF 143/319 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.078); catalogued as COSV58297979; called by muse, mutect2, varscan2
- PLAAT4 | c.21G>T p.E7D | Missense Mutation (SNP) | VAF 82/190 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55372651; called by muse, mutect2, varscan2
- PPL | c.2607+1G>A p.X869_splice | Splice Site (SNP) | VAF 36/63 reads (57%) | catalogued as COSV52165827; called by muse, mutect2, varscan2
- SCNN1G | c.838C>T p.H280Y | Missense Mutation (SNP) | VAF 57/97 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs543639039, COSV55597305; called by muse, mutect2, varscan2
- SLC39A11 | c.76G>T p.A26S | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.159); catalogued as COSV99722490; called by muse, mutect2, varscan2
- SLFN5 | c.1198C>T p.H400Y | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100249538; called by muse, mutect2
- SUN2 | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as COSV99325372; called by muse, mutect2
- TDG | c.983C>T p.A328V | Missense Mutation (SNP) | VAF 69/199 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV57165123; called by muse, mutect2, varscan2
- ZNF479 | c.1411G>A p.G471S | Missense Mutation (SNP) | VAF 138/382 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV100482846, COSV58636035; called by muse, mutect2, varscan2
- GREB1 | c.806_821del p.A269Vfs*27 | Frame Shift Del (DEL) | VAF 29/127 reads (23%) | called by mutect2, pindel, varscan2
- PSME2 | c.361-21_383del p.X121_splice | Splice Site (DEL) | VAF 12/44 reads (27%) | called by mutect2, pindel
- CDC14B | c.1464C>T p.L488= (on ENST00000375241 / NM_033331.4; = p.L449= on NM_003671.5) | Silent (SNP) | VAF 44/150 reads (29%) | catalogued as rs754546622, COSV55784834; called by muse, mutect2, varscan2
- HMCN1 | c.12381C>T p.V4127= | Silent (SNP) | VAF 71/217 reads (33%) | catalogued as COSV54879009; called by muse, mutect2, varscan2
- ILDR2 | c.597C>T p.L199= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs758891563, COSV54828819; called by muse, mutect2, varscan2
- OR6V1 | c.831A>T p.S277= | Silent (SNP) | VAF 26/258 reads (10%) | catalogued as COSV101389226; called by muse, mutect2, varscan2
- PI15 | c.291T>A p.L97= | Silent (SNP) | VAF 155/392 reads (40%) | catalogued as COSV52639679; called by muse, mutect2, varscan2
- PTPRN2 | c.2445G>A p.A815= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as rs139538258; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC39A11 | c.75G>C p.G25= | Silent (SNP) | VAF 41/105 reads (39%) | catalogued as COSV99722494; called by muse, mutect2, varscan2
- ZNF592 | c.1782C>T p.D594= | Silent (SNP) | VAF 48/71 reads (68%) | catalogued as rs138523629; called by muse, mutect2, varscan2
- GLG1 | c.*1069A>C | 3'UTR (SNP) | VAF 77/94 reads (82%) | catalogued as COSV52664112; called by muse, mutect2, varscan2
